Somatic mutation profile of tumor specimen 0DEV4B from CCDI case PBBPWK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.6 years (3,863 days).
Specimen 0DEV4B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43c15c4c-4b66-4b4e-ac83-d1f882214837.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEV2C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fb886a2-bb58-4767-95c0-70f420d9e9f8

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Intron 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A1 | c.4576C>T p.P1526S | Missense Mutation (SNP) | VAF 75/384 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1263510887; called by muse, mutect2, varscan2
- OR5W2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60615459; called by muse, mutect2, varscan2
- PDCD7 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs774717943, COSV52600475; called by muse, mutect2, varscan2
- PMEL | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756974126, COSV59385503; called by muse, mutect2, varscan2
- PTCH1 | c.1987C>T p.Q663* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as CM971261, COSV59483146; called by mutect2, varscan2
- SELE | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 137/342 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV60974243; called by muse, mutect2, varscan2
- SHROOM3 | c.3584G>A p.G1195E | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs766138868; called by muse, mutect2, varscan2
- TPTE2 | c.326G>A p.R109H (on ENST00000400230 / NM_199254.2; = p.R72H on NM_130785.3) | Missense Mutation (SNP) | VAF 182/530 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs761018097, COSV55028787; called by muse, mutect2, varscan2
- ABCA13 | c.5006C>G p.T1669S | Missense Mutation (SNP) | VAF 88/417 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ASMT | c.932A>G p.E311G (on ENST00000381229; = p.E339G on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/351 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CFAP65 | c.1824G>T p.Q608H | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); called by muse, mutect2
- DNAH6 | c.2610G>T p.K870N | Missense Mutation (SNP) | VAF 177/380 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- FPGT | c.559dup p.S187Kfs*6 | Frame Shift Ins (INS) | VAF 248/536 reads (46%) | called by mutect2, varscan2
- KIAA0232 | c.3652T>C p.S1218P | Missense Mutation (SNP) | VAF 178/450 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5M8 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- PSMC1 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AK9 | c.1020T>C p.P340= | Silent (SNP) | VAF 133/398 reads (33%) | catalogued as rs914613471; called by muse, mutect2, varscan2
- BMS1 | c.3399C>T p.G1133= | Silent (SNP) | VAF 199/459 reads (43%) | catalogued as rs750036687; called by muse, mutect2, varscan2
- CD38 | c.543C>T p.S181= | Silent (SNP) | VAF 127/637 reads (20%) | called by muse, mutect2, varscan2
- CSMD2 | c.4506C>T p.Y1502= | Silent (SNP) | VAF 125/328 reads (38%) | catalogued as rs767215580, COSV53884302; called by muse, mutect2, varscan2
- KLHL29 | c.2076C>T p.G692= | Silent (SNP) | VAF 67/212 reads (32%) | catalogued as rs377147451; called by muse, mutect2, varscan2
- HEY1 | c.250-23T>C | Intron (SNP) | VAF 161/392 reads (41%) | catalogued as rs1479949167; called by muse, mutect2, varscan2
- PON1 | c.75-86G>C | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2
